Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A94Y, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A94Y-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site Cervix NOS C53.9
QW 3/12/14

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

"Biopsy of uterine cervix":

Squamous cell carcinoma, invasive and ulcerated, extensively necrotic.

Item	Yes	No
ICD-O Discrepancy		☒
ICD-A Discrepancy		☒
ICD-Malignancy History		☒

Source: NCI Genomic Data Commons file 9d12fa27-7cab-4a03-8691-b83288fac8c2 (TCGA-VS-A94Y.CBBFD564-A58A-42D3-89B8-682858D13B50.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).